Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A27C, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A27C-01A (Primary Tumor).

[page 1 of 4]
105-0-3

carcinoma, papillary transitional cell 8/30/3

Site: bladder NOS C67.9

hw
5/26/11UID: F8FF65C1-F032-4CED-A0EA-FFDBA1E25DC2

IRB APPROVED

Form Revised

Fax:

Clinical Case Report

(for Collection of Cancerous Tissue)

Informed Consent

Reviewed/Not Reviewed	hw 5/26/11	5/15/11

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	Blood Pressure	Heart Rate
☒ Male ☐ Female	59kg	☐ Divorced ☐ Widow	12/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: lower abdominal pain; fever; blood in the urine
Symptoms: weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 4]
ID#:

PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink	2.0 (yrs)	5 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____	11	CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____	11	CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☒ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 4]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumour was found in the urinary bladder.	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Urinary Bladder Cancer	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T ₃ N ₀ M ₀ Stage: III	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Resection of total Urinary Bladder		
Primary Tumor		
Organ	Detailed Location	Size
Urinary bladder	TRITON	4.5 x 1 x 1 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T ₃ N ₀ M ₀ Stage: III		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 4]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
02	02	02	02			02	02
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Urinary bladder	1.5 x 1 x 1 cm		5 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT3	N0	M0	Stage: III
Notes:			

Source: NCI Genomic Data Commons file eb596cb9-405a-42bf-80ac-ffc28c7c6dc9 (TCGA-CF-A27C.F8FF65C1-F032-4CED-A0EA-FFDBA1E25DC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).